Somatic mutation profile of tumor specimen TCGA-ER-A19H-06A (aliquot TCGA-ER-A19H-06A-12D-A196-08) from TCGA case TCGA-ER-A19H, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 50.7 years (18,508 days).
Specimen TCGA-ER-A19H-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d0bf88b-1374-44cf-b3e2-34731f24de32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19H-10A (Blood Derived Normal), aliquot TCGA-ER-A19H-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a6e763e-a9b8-423f-8f9b-0c349210d049

The open-access MAF lists 314 somatic variants for this specimen: 199 protein-altering or splice-affecting, 107 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 183, Silent 107, Nonsense Mutation 9, Intron 3, Splice Site 3, RNA 3, Frame Shift Del 2, 5'UTR 1, 3'UTR 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/99 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.458-1G>A p.X153_splice | Splice Site (SNP) | VAF 66/110 reads (60%) | hotspot (GDC flag); catalogued as CS127044, COSV58686546, COSV58687455, COSV58704542; called by muse, varscan2
- CNOT1 | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1567417422, COSV57765440; ClinVar: pathogenic / uncertain significance; called by mutect2, varscan2
- COL3A1 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs121912927, CM000320, CM000321, COSV58583853, COSV58594006; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.3955C>T p.R1319* | Nonsense Mutation (SNP) | VAF 31/58 reads (53%) | catalogued as rs1180309541, CM151372, COSV70341700; ClinVar: pathogenic; called by mutect2, varscan2
- AC098582.1 | c.3013C>T p.P1005S | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52018300; called by muse, varscan2
- ADAM21 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV50789348; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV56474489; called by muse, mutect2, varscan2
- ADAMTSL5 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57860217; called by muse, mutect2, varscan2
- ADCY10 | c.2920C>T p.P974S | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.311); catalogued as rs777782090, COSV63239033; called by muse, mutect2, varscan2
- ADGRB3 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65387063; called by muse, mutect2, varscan2
- AGO1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64594805; called by muse, mutect2, varscan2
- AHNAK2 | c.13288G>A p.E4430K | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV100316335, COSV60910010; called by muse, mutect2, varscan2
- AKNA | c.2932C>T p.P978S | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.454); catalogued as COSV56311511; called by muse, mutect2, varscan2
- ALDH1B1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 70/104 reads (67%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV66619367, COSV66620102; called by muse, varscan2
- ANKRD50 | c.1104A>T p.E368D | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.201); catalogued as COSV72385256; called by muse, mutect2, varscan2
- ANO2 | c.2197G>A p.E733K (on ENST00000356134 / NM_001278597.3; = p.E737K on NM_001278596.3) | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs375652166; called by muse, mutect2, varscan2
- APC2 | c.3077G>A p.R1026Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1158880317, COSV52016599; called by muse, mutect2, varscan2
- ARHGEF28 | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.18); PolyPhen benign (0.104); catalogued as rs745950913, COSV55249892; called by mutect2, varscan2
- ARID1A | c.3368C>T p.S1123F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV61373476; called by muse, mutect2, varscan2
- ATP13A5 | c.2629C>T p.P877S | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV60866913; called by muse, mutect2, varscan2
- ATP4A | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1035958833, COSV52866454; called by muse, mutect2, varscan2
- ATP8B4 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52711060; called by muse, mutect2, varscan2
- ATXN2 | c.1514C>T p.S505F (on ENST00000550104; = p.S345F on NM_002973.4) | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV66481852; called by muse, varscan2
- BAG6 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 83/337 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52988769; called by muse, mutect2, varscan2
- BAZ1B | c.1551A>T p.E517D | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV59989391; called by muse, mutect2, varscan2
- BCKDK | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as COSV54890850; called by muse, mutect2, varscan2
- BRINP3 | c.796A>G p.N266D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); catalogued as COSV66516095; called by muse, mutect2, varscan2
- BRIP1 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs756269682, COSV51995791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTK | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 69/88 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV58117942; called by muse, mutect2, varscan2
- BTN1A1 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV55066892, COSV99764145; called by muse, mutect2, varscan2
- C12orf50 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 23/91 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as COSV53893989; called by muse, mutect2, varscan2
- C1orf194 | c.137G>A p.R46Q (on ENST00000369948 / NM_001245025.3; = p.R34Q on NM_001122961.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs200958119; called by muse, mutect2, varscan2
- CA2 | c.544G>C p.G182R | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV53405602; called by muse, mutect2, varscan2
- CACNA1C | c.2845G>T p.A949S | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV59702735; called by muse, mutect2, varscan2
- CALCB | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs770182897, COSV60834224; called by muse, mutect2, varscan2
- CALCB | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs369737294; called by mutect2, varscan2
- CAPZA3 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV56850026; called by muse, mutect2, varscan2
- CD163 | c.2051G>A p.G684E | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs867856331, COSV63130442; called by muse, mutect2, varscan2
- CD1C | c.911G>A p.W304* | Nonsense Mutation (SNP) | VAF 104/276 reads (38%) | catalogued as COSV63805898; called by muse, mutect2, varscan2
- CD226 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT tolerated (0.5); PolyPhen benign (0.297); catalogued as rs1358404350, COSV54610640; called by mutect2, varscan2
- CFAP61 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760800263, COSV55622175; called by muse, mutect2, varscan2
- CFH | c.3463G>A p.G1155R | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as CM162980, COSV66406602; called by muse, mutect2, varscan2
- CFHR4 | c.1592G>A p.G531E (on ENST00000367416 / NM_001201551.2; = p.G285E on NM_006684.5) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.379); catalogued as COSV52224734; called by muse, mutect2, varscan2
- CLHC1 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63427082; called by muse, mutect2, varscan2
- CLPB | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 92/356 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53628026; called by muse, mutect2, varscan2
- CNTN4 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.924); catalogued as rs1349406131, COSV61869503, COSV61881190; called by muse, mutect2, varscan2
- COL21A1 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs771765654, COSV55156257; called by mutect2, varscan2
- COL22A1 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.255); catalogued as COSV57327858; called by muse, mutect2, varscan2
- COL9A1 | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57880462; called by muse, varscan2
- DDX39B | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63331114; called by muse, mutect2, varscan2
- DEFB115 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as rs866556239, COSV68723000; called by muse, mutect2, varscan2
- DENND6B | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV101306021; called by mutect2, varscan2
- DMXL2 | c.7477G>A p.D2493N | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.149); catalogued as COSV51842186; called by muse, mutect2, varscan2
- DNAH8 | c.7982G>A p.R2661Q | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775011889, COSV59431338, COSV59459216; called by mutect2, varscan2
- DNAH8 | c.8428C>T p.R2810* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as rs747550558, COSV59431354; called by mutect2, varscan2
- DNER | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV59161912; called by mutect2, varscan2
- DPYD | c.1732C>T p.L578F | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286575905, COSV64589756, COSV64594991; called by muse, mutect2, varscan2
- DYSF | c.4244C>T p.P1415L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50277810; called by muse, mutect2, varscan2
- EBF1 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV100565168; called by muse, mutect2, varscan2
- EBF1 | c.637-1G>A p.X213_splice | Splice Site (SNP) | VAF 14/16 reads (88%) | catalogued as COSV100565170; called by muse, mutect2, varscan2
- ELFN2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1176640464, COSV68744053; called by muse, mutect2, varscan2
- EPB41L1 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.239); catalogued as rs769375731, COSV52440505; called by mutect2, varscan2
- ESPNL | c.2805G>A p.W935* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as rs1279748417, COSV58032577; called by muse, mutect2, varscan2
- ESR2 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.418); catalogued as rs757686092, COSV50829136; called by muse, mutect2, varscan2
- EXPH5 | c.3377C>T p.P1126L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56199717; called by muse, mutect2, varscan2
- FAT3 | c.4637G>A p.R1546Q | Missense Mutation (SNP) | VAF 118/455 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs746923546, COSV53086601, COSV53187272; called by muse, varscan2
- FGF16 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs188208804, COSV71546176; called by muse, mutect2
- FN1 | c.5146G>A p.G1716R | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV60548274; called by muse, mutect2, varscan2
- FRG2B | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.316); catalogued as COSV71042699, COSV71043031; called by muse, mutect2, varscan2
- FUT9 | c.872A>T p.D291V | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56143496; called by muse, mutect2, varscan2
- GALNT14 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1008335995, COSV100204079; called by muse, mutect2, varscan2
- GIMAP1 | c.620T>A p.M207K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100211933; called by mutect2, varscan2
- GIMAP1 | c.621G>T p.M207I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV100211935; called by mutect2, varscan2
- GLYAT | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.338); catalogued as COSV53538641; called by muse, mutect2, varscan2
- GPLD1 | c.965A>G p.Y322C | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.718); catalogued as rs1168361607, COSV100015016; called by muse, mutect2, varscan2
- GPR75 | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100765888; called by muse, mutect2, varscan2
- GRIA2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.893); catalogued as COSV52384819; called by muse, mutect2, varscan2
- GRIA2 | c.2183C>T p.T728M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348382463, COSV52384836; called by mutect2, varscan2
- GRIN2B | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV74205095; called by mutect2, varscan2
- GUCY2D | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV54694861; called by muse, mutect2, varscan2
- HERC2 | c.11162A>G p.D3721G | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV55312408; called by muse, mutect2, varscan2
- HK2 | c.656A>T p.Y219F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.373); catalogued as COSV51873791; called by muse, mutect2, varscan2
- HLCS | c.2023C>T p.H675Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs368743397; called by muse, mutect2, varscan2
- HOMER2 | c.647C>T p.S216F (on ENST00000304231 / NM_199330.3; = p.S205F on NM_004839.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV58484765; called by muse, mutect2, varscan2
- IGSF3 | c.1610C>T p.S537F (on ENST00000369486 / NM_001007237.3; = p.S557F on NM_001542.4) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV59587800; called by muse, mutect2, varscan2
- ILVBL | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747633829, COSV54618387; called by muse, mutect2, varscan2
- ITGA7 | c.1754C>T p.P585L (on ENST00000555728; = p.P541L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.161); catalogued as COSV57692823; called by muse, varscan2
- ITGB4 | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748038104, COSV52322746; called by mutect2, varscan2
- JADE2 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs754660916, COSV50912296; called by muse, mutect2, varscan2
- JPH2 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs762277300, COSV65902273; called by muse, mutect2, varscan2
- KHDC3L | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64868860; called by mutect2, varscan2
- KIAA0319 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65496934; called by muse, mutect2, varscan2
- KIAA0753 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748721188, COSV63816939; called by muse, varscan2
- KIF18A | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs372168668, COSV54181738; called by mutect2, varscan2
- KLHDC7A | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs780616009, COSV68769217; called by muse, varscan2
- KLK15 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.823); catalogued as rs765876178, COSV56826027, COSV56827217; called by muse, mutect2, varscan2
- KLK3 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.1); PolyPhen benign (0.399); catalogued as rs138565183, COSV58099332; called by muse, mutect2, varscan2
- KMT2D | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs755350858, COSV56419702; called by muse, mutect2, varscan2
- LANCL1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV52064453; called by muse, mutect2, varscan2
- LIPI | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as COSV100753792, COSV60709176, COSV60709881; called by muse, mutect2, varscan2
- LRP1B | c.11834G>A p.G3945E | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.999); catalogued as COSV67196683, COSV67230129; called by muse, mutect2, varscan2
- LRP1B | c.11833G>A p.G3945R | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.999); catalogued as rs770860780, COSV67196685; called by muse, mutect2
- LRP1B | c.2602G>A p.D868N | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as rs1015312571, COSV63341598; called by mutect2, varscan2
- LUZP2 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs369078244, COSV61198069; called by mutect2, varscan2
- MAGEC3 | c.258G>A p.K86= | Splice Region (SNP) | VAF 31/48 reads (65%) | catalogued as COSV100026096, COSV53577218; called by muse, mutect2, varscan2
- MBOAT2 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60008021; called by muse, mutect2, varscan2
- MIA2 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs200876456, COSV54481706; called by muse, mutect2, varscan2
- MPL | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs866559375, COSV65244294; called by muse, varscan2
- MRI1 | c.67A>T p.K23* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV50003809; called by muse, varscan2
- MTR | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63964104; called by muse, mutect2, varscan2
- MUC16 | c.12821C>T p.P4274L | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as COSV67452272, COSV67468854; called by muse, mutect2, varscan2
- MXRA5 | c.8274G>A p.M2758I | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV54227767, COSV99028453; called by muse, mutect2, varscan2
- MYOCD | c.2351C>T p.S784F | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV58499110; called by muse, mutect2, varscan2
- MYT1 | c.3098C>T p.S1033F | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV60502116, COSV60514003; called by muse, mutect2, varscan2
- NCAM1 | c.2072G>A p.G691E (on ENST00000316851 / NM_181351.5; = p.G681E on NM_000615.7) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57510911; called by muse, mutect2, varscan2
- NEK2 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1372194983, COSV65355244; called by muse, mutect2, varscan2
- NINL | c.1972A>G p.R658G | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs1247584174, COSV53999667; called by muse, varscan2
- NKAIN2 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63647248; called by muse, mutect2, varscan2
- NLRP1 | c.1879C>T p.Q627* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV52560759; called by muse, mutect2, varscan2
- NPY4R | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV65397717; called by mutect2, varscan2
- OR4S2 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56746138; called by muse, mutect2, varscan2
- OR51G1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58968644; called by muse, mutect2, varscan2
- OR51S1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs142743963; called by muse, mutect2, varscan2
- OR52H1 | c.458G>A p.R153Q (on ENST00000322653; = p.R159Q on NM_001005289.1) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as rs571302036, COSV59504840; called by mutect2, varscan2
- OR5P2 | c.43T>C p.F15L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV61490106; called by muse, mutect2, varscan2
- OR5P3 | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs751559219, COSV60429060; called by muse, mutect2, varscan2
- OVGP1 | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.23); catalogued as COSV63857810; called by muse, mutect2, varscan2
- P3H2 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as COSV60019280; called by muse, mutect2, varscan2
- PAPPA2 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV62774669; called by muse, mutect2, varscan2
- PAPPA2 | c.5111T>G p.M1704R | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV62792693; called by muse, mutect2, varscan2
- PCDH15 | c.389A>T p.Y130F | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV57273420; called by muse, mutect2, varscan2
- PCDHGA8 | c.1948G>A p.G650S | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53913007, COSV99539177; called by muse, mutect2, varscan2
- PCLO | c.5617A>G p.S1873G | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.915); catalogued as COSV61621868; called by muse, mutect2, varscan2
- PCLO | c.5189C>T p.S1730F | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100427537; called by muse, mutect2, varscan2
- PDE4DIP | c.4427C>T p.S1476F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587746082, COSV57681933; called by muse, varscan2
- PDZD7 | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64645646; called by muse, mutect2, varscan2
- PER3 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs145870917; called by mutect2, varscan2
- PGM1 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64302490; called by muse, mutect2, varscan2
- PKIA | c.16A>G p.T6A | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV61913701; called by muse, mutect2, varscan2
- PLS3 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 115/134 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV56776831; called by muse, mutect2, varscan2
- POM121L12 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV68692448; called by mutect2, varscan2
- PPFIBP1 | c.1784+1G>A p.X595_splice (on ENST00000318304 / NM_177444.3; = p.X589_splice on NM_003622.4) | Splice Site (SNP) | VAF 17/90 reads (19%) | catalogued as COSV57288859; called by muse, mutect2, varscan2
- PPIL2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs747511514, COSV58605189; called by mutect2, varscan2
- PPIP5K1 | c.4190C>T p.T1397I (on ENST00000396923; = p.T1372I on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV55806912; called by muse, mutect2, varscan2
- PPL | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52166427, COSV52170538; called by muse, mutect2, varscan2
- PREX2 | c.984G>A p.W328* | Nonsense Mutation (SNP) | VAF 43/106 reads (41%) | catalogued as COSV55757115; called by muse, mutect2, varscan2
- PRKAA2 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 112/261 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64802530; called by muse, mutect2, varscan2
- PTPRK | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV63892970; called by muse, mutect2, varscan2
- PUM1 | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as COSV57082639; called by muse, mutect2, varscan2
- RABGAP1 | c.508A>G p.M170V | Missense Mutation (SNP) | VAF 77/113 reads (68%) | SIFT tolerated (0.93); PolyPhen benign (0.038); catalogued as rs748492879, COSV58059842; called by muse, mutect2, varscan2
- RET | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.443); catalogued as rs1478152005, COSV60688829; called by mutect2, varscan2
- RFX6 | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV60583906; called by muse, mutect2, varscan2
- RPS6KA6 | c.2121G>A p.M707I | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs754433259, COSV53117283; called by muse, mutect2, varscan2
- RPTOR | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV60804804; called by muse, mutect2, varscan2
- RYR1 | c.13774G>A p.D4592N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.435); catalogued as rs572103362, COSV62091842; called by mutect2, varscan2
- SAMSN1 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867869414, COSV53467504; called by muse, mutect2, varscan2
- SDK2 | c.6219T>G p.F2073L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66182682; called by muse, mutect2, varscan2
- SEMA3C | c.1343T>A p.F448Y | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54843122; called by mutect2, varscan2
- SERPINA3 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.218); catalogued as rs1319307412, COSV67585477; called by muse, mutect2, varscan2
- SERTAD4 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs373437236; called by mutect2, varscan2
- SETDB1 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as rs761509888, COSV54978475; called by muse, mutect2, varscan2
- SETMAR | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.148); catalogued as COSV100740830; called by mutect2, varscan2
- SETMAR | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV100740831; called by muse, mutect2, varscan2
- SIM1 | c.1387C>T p.H463Y | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.026); catalogued as COSV53489770; called by muse, mutect2, varscan2
- SLC26A9 | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs758627816, COSV61601280; called by muse, mutect2, varscan2
- SLC37A2 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV53520966; called by muse, mutect2, varscan2
- SLC6A14 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV64140830; called by muse, mutect2, varscan2
- SLC8A1 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.272); catalogued as COSV60473814; called by muse, mutect2, varscan2
- SMPDL3A | c.562A>G p.R188G | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV63755180; called by muse, mutect2, varscan2
- SPAG17 | c.5171C>T p.S1724L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs535296861, COSV60454725; called by mutect2, varscan2
- SPAG17 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs751561514, COSV60454735; called by muse, mutect2, varscan2
- SPTBN5 | c.2903C>T p.S968F | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.043); catalogued as COSV58017699; called by muse, mutect2, varscan2
- ST3GAL2 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 12/90 reads (13%) | PolyPhen probably damaging (1); catalogued as COSV61595878; called by muse, mutect2, varscan2
- SUCO | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV55263048; called by muse, mutect2, varscan2
- SVEP1 | c.2599G>A p.G867R | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57031281; called by muse, mutect2, varscan2
- SZRD1 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV100130601, COSV59185570; called by muse, mutect2, varscan2
- TDRD1 | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.95); catalogued as COSV52588596; called by muse, mutect2, varscan2
- TECTA | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.271); catalogued as rs867836820, COSV50691680, COSV50779839; called by muse, mutect2, varscan2
- TENM3 | c.5078G>A p.R1693K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV69299284, COSV69301725; called by muse, mutect2
- TIAM2 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100018738, COSV59690779; called by muse, varscan2
- TMEM225 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773180306, COSV66692942; called by mutect2, varscan2
- TNXB | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 99/185 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV64475120, COSV64479831; called by muse, mutect2, varscan2
- TPM2 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 94/170 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1211830756, COSV100253399, COSV61405171; called by muse, varscan2
- TRIM60 | c.1085G>A p.W362* | Nonsense Mutation (SNP) | VAF 63/115 reads (55%) | catalogued as COSV61969980; called by muse, mutect2, varscan2
- TRIO | c.1442A>G p.E481G | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60079325; called by muse, mutect2, varscan2
- TTN | c.38979G>T p.K12993N (on ENST00000591111; = p.K5569N on NM_003319.4) | Missense Mutation (SNP) | VAF 19/85 reads (22%) | PolyPhen possibly damaging (0.865); catalogued as COSV59932793; called by mutect2, varscan2
- TTN | c.14590G>A p.G4864R (on ENST00000591111; = p.G3937R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | PolyPhen benign (0); catalogued as rs1477393359, COSV59932820, COSV59970683; called by muse, mutect2, varscan2
- TTN | c.10832C>T p.S3611F (on ENST00000591111; = p.S3565F on NM_003319.4) | Missense Mutation (SNP) | VAF 96/180 reads (53%) | catalogued as rs267599075, COSV100594782, COSV59977724; called by muse, mutect2, varscan2
- WDR49 | c.1409C>T p.S470L (on ENST00000308378 / NM_001366158.1; = p.S811L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57702516, COSV57702668; called by mutect2, varscan2
- XPO1 | c.850G>T p.V284L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV68945019; called by muse, mutect2, varscan2
- ZNF331 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53475481, COSV53477209; called by muse, mutect2, varscan2
- ZNF451 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV62596932; called by muse, mutect2, varscan2
- ZNF804A | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV56438577; called by muse, mutect2, varscan2
- ZNF99 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV68054889; called by muse, mutect2, varscan2
- PRAMEF14 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PSG9 | c.265del p.I89Lfs*20 | Frame Shift Del (DEL) | VAF 72/226 reads (32%) | called by mutect2, pindel, varscan2
- RNF213 | c.14301_14304delinsATT p.L4768Ffs*11 | Frame Shift Del (DEL) | VAF 35/86 reads (41%) | called by pindel, varscan2*
- TMEM185A | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.241); called by mutect2, varscan2
- ABCC8 | c.2469G>A p.G823= | Silent (SNP) | VAF 49/232 reads (21%) | catalogued as COSV56847416; called by muse, varscan2
- ACP7 | c.750C>T p.L250= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV58698484; called by muse, mutect2, varscan2
- ACSF2 | c.924C>T p.P308= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs780305324, COSV51971655; called by muse, mutect2, varscan2
- ADAMTS16 | c.1497G>A p.K499= | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as COSV56981864; called by muse, mutect2, varscan2
- AHNAK | c.14550C>T p.S4850= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV57206307; called by muse, mutect2, varscan2
- AHNAK | c.1593C>T p.G531= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as COSV57206318; called by muse, mutect2, varscan2
- AHSP | c.243C>T p.F81= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV56528649; called by muse, mutect2, varscan2
- APOB | c.10683C>T p.S3561= | Silent (SNP) | VAF 242/580 reads (42%) | catalogued as COSV51927187; called by muse, mutect2, varscan2
- ASH1L | c.6732C>T p.L2244= (on ENST00000368346 / NM_001366177.2; = p.L2239= on NM_018489.3) | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs555295173, COSV64206272; called by muse, mutect2, varscan2
- ATP13A2 | c.729C>T p.F243= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs758939736, COSV58698699; called by muse, mutect2, varscan2
- BCL2L12 | c.24C>T p.F8= | Silent (SNP) | VAF 46/78 reads (59%) | catalogued as COSV55862291; called by muse, mutect2, varscan2
- BCL3 | c.1080G>T p.G360= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV51233899; called by muse, varscan2
- BRCA2 | c.4350T>C p.F1450= | Silent (SNP) | VAF 103/155 reads (66%) | catalogued as COSV66450007; called by muse, mutect2, varscan2
- BSN | c.5316C>T p.A1772= | Silent (SNP) | VAF 26/40 reads (65%) | catalogued as COSV56514204; called by muse, mutect2, varscan2
- C11orf45 | c.219A>G p.V73= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs1489793292, COSV57964032; called by muse, mutect2, varscan2
- C12orf60 | c.444C>T p.I148= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV57451291; called by mutect2, varscan2
- C1R | c.2076C>A p.I692= (on ENST00000536053 / NM_001354346.2; = p.I678= on NM_001733.7) | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV73382848; called by muse, mutect2, varscan2
- CAAP1 | c.852C>T p.V284= | Silent (SNP) | VAF 96/179 reads (54%) | catalogued as COSV61700375, COSV61701806; called by muse, mutect2, varscan2
- CASZ1 | c.1134C>T p.V378= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1268767141, COSV59733053; called by muse, mutect2, varscan2
- CBLIF | c.174G>A p.L58= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV57238239; called by muse, mutect2, varscan2
- CCDC148 | c.1656C>T p.F552= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as rs772008293, COSV51756150; called by muse, mutect2, varscan2
- CCDC9B | c.216C>T p.A72= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV66874925; called by muse, mutect2, varscan2
- CENPJ | c.618A>T p.G206= | Silent (SNP) | VAF 51/76 reads (67%) | catalogued as rs1208915076, COSV67883134; called by mutect2, varscan2
- CFAP91 | c.1494C>T p.Y498= | Silent (SNP) | VAF 96/144 reads (67%) | catalogued as COSV56339728, COSV56344626; called by muse, varscan2
- CIDEA | c.615G>A p.R205= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as rs750276427, COSV57597689; called by muse, mutect2, varscan2
- CSMD1 | c.9684G>A p.Q3228= (on ENST00000520002; = p.Q3227= on NM_033225.6) | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100151335, COSV59294455; called by muse, mutect2, varscan2
- DCAF4L2 | c.1029C>T p.L343= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs1319543135, COSV60477117; called by muse, mutect2, varscan2
- DECR2 | c.735C>T p.I245= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs372246299; called by mutect2, varscan2
- DISP2 | c.852G>A p.K284= | Silent (SNP) | VAF 54/109 reads (50%) | catalogued as COSV51117496; called by muse, mutect2, varscan2
- DNAH9 | c.5859C>T p.F1953= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs767462083, COSV52339383; called by mutect2, varscan2
- DOCK10 | c.285A>T p.T95= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99287696; called by muse, mutect2, varscan2
- DRD2 | c.1311C>T p.F437= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV60755376; called by muse, mutect2, varscan2
- DSCAM | c.1395G>T p.V465= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV101261179, COSV68022729; called by mutect2, varscan2
- EFHD2 | c.340C>T p.L114= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV65657900; called by muse, mutect2, varscan2
- FAM13C | c.894G>A p.R298= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV53244755; called by muse, mutect2, varscan2
- FAM181A | c.438C>T p.G146= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV50887897; called by mutect2, varscan2
- GCN1 | c.6933C>T p.I2311= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV56104989; called by muse, mutect2, varscan2
- GLT1D1 | c.819C>T p.I273= (on ENST00000442111 / NM_001366889.1; = p.I193= on NM_144669.3) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV55879411; called by muse, varscan2
- GPLD1 | c.966T>C p.Y322= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as COSV100015014; called by muse, mutect2, varscan2
- GPR148 | c.771C>T p.S257= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV59307730; called by muse, mutect2, varscan2
- GPR152 | c.582G>A p.R194= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV56885280; called by muse, mutect2, varscan2
- GPR61 | c.819G>A p.Q273= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV63983372; called by muse, mutect2, varscan2
- GPR63 | c.654C>T p.P218= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as rs370572252; called by muse, mutect2, varscan2
- GRID2 | c.1863G>A p.G621= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV56182125; called by muse, mutect2, varscan2
- HAPLN1 | c.276G>A p.V92= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as rs774195625, COSV57145984; called by muse, varscan2
- HEATR4 | c.2679G>A p.E893= | Silent (SNP) | VAF 27/38 reads (71%) | catalogued as COSV58373651; called by muse, mutect2, varscan2
- HIVEP3 | c.492C>T p.F164= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as rs772680628, COSV56009413; called by muse, mutect2, varscan2
- IGF1R | c.522C>T p.P174= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV51272516; called by muse, mutect2
- INS-IGF2 | c.105G>A p.L35= | Silent (SNP) | VAF 64/170 reads (38%) | catalogued as COSV51746682; called by muse, mutect2, varscan2
- MARK3 | c.1575C>T p.G525= | Silent (SNP) | VAF 60/82 reads (73%) | catalogued as COSV53507502; called by mutect2, varscan2
- ME3 | c.405C>T p.I135= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs769320037, COSV60164394; called by mutect2, varscan2
- MMP16 | c.1008C>T p.P336= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs761488939, COSV54153288, COSV54174570, COSV54183762; called by mutect2, varscan2
- MOGS | c.975C>T p.T325= | Silent (SNP) | VAF 54/169 reads (32%) | catalogued as COSV51968534; called by muse, mutect2, varscan2
- MUC17 | c.228C>T p.V76= | Silent (SNP) | VAF 46/66 reads (70%) | catalogued as rs755764209, COSV60282555; called by mutect2, varscan2
- MYH1 | c.3651G>A p.V1217= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV56844982; called by mutect2, varscan2
- MYLK2 | c.1320G>A p.K440= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV65658715; called by muse, mutect2, varscan2
- MYO9A | c.4242A>G p.S1414= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as COSV61848578; called by muse, mutect2, varscan2
- NEK2 | c.771C>T p.Y257= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs1159284015, COSV65355378; called by muse, mutect2, varscan2
- NOVA1 | c.1323G>A p.G441= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV57471481; called by muse, mutect2, varscan2
- NYAP1 | c.600C>T p.S200= | Silent (SNP) | VAF 54/65 reads (83%) | catalogued as COSV55717734; called by muse, mutect2, varscan2
- OR6Y1 | c.16C>T p.L6= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as rs766724500, COSV56928619; called by muse, mutect2, varscan2
- OSBPL7 | c.1932C>T p.V644= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV50107241, COSV50114619; called by muse, mutect2, varscan2
- P2RX3 | c.447C>T p.I149= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1348669746, COSV54441713; called by muse, mutect2, varscan2
- PAPPA2 | c.3582G>A p.R1194= | Silent (SNP) | VAF 57/129 reads (44%) | catalogued as COSV62792684; called by muse, varscan2
- PCLO | c.5190C>T p.S1730= | Silent (SNP) | VAF 54/123 reads (44%) | catalogued as rs868336107, COSV100427536; called by muse, mutect2, varscan2
- PDE3A | c.1080C>T p.L360= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV62969616; called by muse, mutect2, varscan2
- PFKFB2 | c.645C>T p.F215= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs780777202, COSV65547404; called by muse, mutect2, varscan2
- PGC | c.1041C>T p.V347= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs767505632, COSV57823945; called by mutect2, varscan2
- PLA2G7 | c.168C>T p.I56= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV51258823, COSV51261269; called by muse, mutect2, varscan2
- PLVAP | c.603G>A p.V201= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV53083873; called by mutect2, varscan2
- POF1B | c.1263A>G p.E421= | Silent (SNP) | VAF 72/88 reads (82%) | catalogued as COSV53131625; called by muse, mutect2, varscan2
- POLR2A | c.1293C>T p.F431= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV59490188; called by muse, mutect2, varscan2
- PRAMEF1 | c.915A>G p.L305= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as rs1445484307, COSV60006827; called by muse, mutect2, varscan2
- PRDM9 | c.2301G>A p.Q767= | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as COSV57003693; called by muse, varscan2
- PREX2 | c.4638C>T p.I1546= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV55757134; called by mutect2, varscan2
- PRLR | c.1074C>T p.S358= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs954120195, COSV51493700; called by muse, mutect2, varscan2
- PTCH2 | c.1329C>T p.L443= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV64710230; called by muse, mutect2, varscan2
- PTPRF | c.3843C>T p.I1281= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs770307084, COSV63443400; called by muse, mutect2, varscan2
- RPL11 | c.495C>T p.F165= (on ENST00000374550 / NM_001199802.1; = p.F166= on NM_000975.5) | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100999657; called by muse, mutect2, varscan2
- RPS6KL1 | c.627C>T p.S209= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs754519702, COSV63580790; called by mutect2, varscan2
- RSBN1L | c.1677C>T p.P559= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV58506846; called by muse, mutect2, varscan2
- SCARF1 | c.2088G>A p.G696= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs1206180146, COSV53957806; called by muse, mutect2, varscan2
- SDK1 | c.3490C>A p.R1164= | Silent (SNP) | VAF 31/162 reads (19%) | catalogued as COSV67359849; called by muse, mutect2, varscan2
- SEMA3E | c.210C>T p.L70= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs1345542555, COSV57082524; called by muse, mutect2, varscan2
- SGSH | c.1191C>T p.P397= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV58338781; called by muse, mutect2, varscan2
- SI | c.615G>A p.R205= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as rs867555272, COSV52269599; called by muse, mutect2, varscan2
- SIRT5 | c.426C>T p.I142= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs200210777, COSV63079898; called by mutect2, varscan2
- SLAMF1 | c.942C>T p.V314= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs776353415, COSV52501003; called by muse, mutect2, varscan2
- SLC26A7 | c.1179C>T p.V393= | Silent (SNP) | VAF 80/194 reads (41%) | catalogued as COSV52587933; called by mutect2, varscan2
- SLC35F3 | c.111G>A p.Q37= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV64023756; called by muse, mutect2, varscan2
- SLC39A11 | c.924C>T p.D308= (on ENST00000542342 / NM_001159770.2; = p.D301= on NM_139177.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs201576521; called by mutect2, varscan2
- SLC8A3 | c.1047G>A p.K349= | Silent (SNP) | VAF 43/66 reads (65%) | catalogued as COSV63519657; called by muse, mutect2, varscan2
- SMARCA4 | c.1548G>A p.K516= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV60789355; called by muse, mutect2, varscan2
- SPAG17 | c.5463C>A p.L1821= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100309980, COSV60454717, COSV60456789; called by mutect2, varscan2
- SZRD1 | c.378C>T p.P126= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs1372702716, COSV100130606; called by mutect2, varscan2
- TBC1D32 | c.2280C>G p.S760= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV51538466; called by muse, mutect2, varscan2
- TGM7 | c.249C>T p.V83= | Silent (SNP) | VAF 86/166 reads (52%) | catalogued as COSV71772629; called by muse, mutect2, varscan2
- TIAM2 | c.727C>T p.L243= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1245766966, COSV59690785; called by muse, varscan2
- TICRR | c.1626G>A p.Q542= | Silent (SNP) | VAF 37/69 reads (54%) | catalogued as COSV51538892; called by muse, mutect2, varscan2
- TRIM15 | c.355C>T p.L119= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV64989119; called by muse, mutect2
- TTLL7 | c.1569C>T p.T523= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs774211627, COSV53082171; called by muse, mutect2, varscan2
- TTN | c.24666T>C p.C8222= (on ENST00000591111; = p.C7295= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV59932810; called by muse, mutect2, varscan2
- TUBA3C | c.840G>A p.K280= | Silent (SNP) | VAF 39/65 reads (60%) | catalogued as rs773729698, COSV67138970; called by muse, mutect2, varscan2
- UBE4A | c.1140G>A p.K380= (on ENST00000252108 / NM_001204077.2; = p.K387= on NM_004788.4) | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV52803012, COSV52803933; called by muse, mutect2, varscan2
- USH2A | c.8724G>A p.V2908= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as CD045647, COSV100239632, COSV56339180; called by muse, mutect2, varscan2
- VWA3A | c.1281G>A p.L427= | Silent (SNP) | VAF 79/169 reads (47%) | catalogued as rs1415545252, COSV55388860; called by muse, mutect2, varscan2
- XIRP2 | c.3333G>A p.E1111= (on ENST00000628543; = p.E1286= on NM_152381.6) | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as rs1029091251, COSV54687724; called by muse, mutect2, varscan2
- AC064805.2 | n.1838G>A | RNA (SNP) | VAF 21/54 reads (39%) | catalogued as COSV61193097; called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1198C>T | Intron (SNP) | VAF 24/40 reads (60%) | catalogued as rs545158239, COSV56097564; called by muse, mutect2, varscan2
- C11orf40 | n.322G>A | RNA (SNP) | VAF 19/42 reads (45%) | catalogued as rs748935092, COSV100296374; called by muse, varscan2
- DDX41 | c.*595C>T | 3'UTR (SNP) | VAF 54/86 reads (63%) | catalogued as COSV57251319; called by muse, mutect2, varscan2
- ITGB6 | c.-2G>A | 5'UTR (SNP) | VAF 20/71 reads (28%) | catalogued as rs746022026, COSV99324157; called by muse, mutect2, varscan2
- MIR193B | n.16G>A | RNA (SNP) | VAF 70/172 reads (41%) | called by muse, mutect2, varscan2
- PSD3 | c.2176-28123C>T | Intron (SNP) | VAF 74/174 reads (43%) | catalogued as COSV99675309; called by muse, mutect2, varscan2
- SV2C | c.581-20958C>T | Intron (SNP) | VAF 122/181 reads (67%) | called by muse, mutect2, varscan2
